Surgical pathology report (de-identified scan), TCGA case TCGA-44-7671, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-7671-01A (Primary Tumor).

[page 1 of 2]
DEPARTMENT OF PATHOLOGY AND LABORATORY MEDICINE

SURGICAL PATHOLOGY REPORT

Date Coll: [REDACTED]

SPECIMEN

- A. Right upper middle lobe
- B. Level 7
- C. R4
- D. R2

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung mass

GROSS DESCRIPTION

A. Received fresh in a container labeled "right upper middle lobe" is a 197 gm, 19 x 11.8 x 3.5 cm, portion of lung tissue, compatible with right upper and middle lobes. The pleural surface is tan-pink to gray-black, and mottled. There are bronchial stumps averaging 1 cm in length associated with each of the upper and middle lobes. In the hilar region surrounding each bronchial stump there are several gray-black soft rubbery lymph nodes. There is a 3.2 x 2.8 x 2.2 cm. rubbery pale tan lesion which appears to be within the middle lobe, and which extends to within 1 cm from the bronchial stump. The lesion grossly extends to beneath the pleural surface, but does not appear to involve the pleura. The pleural surface overlying the tumor is inked blue. Tissue is submitted for tissue procurement per the clinical request. The parenchyma away from the mass is spongy and tan-pink-red, with some bleb form in the upper lobe. There are no additional mass lesions. [REDACTED].

BLOCK SUMMARY: A1 - bronchial margin, right upper lobe; A2 - vascular margins; A3 - hilar lymph nodes right upper lobe; A4 - bronchial margin right middle lobe; A5 - hilar lymph nodes right middle lobe; A6-A10 - tumor, including relation to pleural surface and adjacent parenchyma; A11,A12 - representative right upper lobe; A13,A14 - right middle lobe away from mass.

B. Received fresh in a container labeled "level 7" are six slightly fragmented portions of soft gray-black tissue compatible with lymph nodes, up to 1.2 cm in greatest dimension. [REDACTED].

C. Received fresh in a container labeled "R4" are five pieces of soft gray-black to tan-gold tissue up to 0.8 cm in greatest dimension. There appear to be three lymph nodes present.

D. Received fresh in a container labeled "R2" are six fragmented soft gray-black to tan-yellow pieces of tissue ranging from 0.3 cm up to 1.1 cm in greatest dimension. Due to the degree of fragmentation, it is difficult to enumerate the lymph nodes. [REDACTED] [REDACTED] [REDACTED]

[page 2 of 2]
MICROSCOPIC DESCRIPTION

The following template summarizes the findings in this case:

Histologic type: Adenocarcinoma (mixed papillary and not otherwise specified), comprising the mass lesion in the right middle lobe in part A.

Histologic grade: Moderately differentiated.

Primary tumor (pT): pT2a. The tumor is 3.2 cm in greatest dimension. Pleural invasion is not identified.

Margins of resection: Negative for tumor

Direct extension of tumor: Not identified

Vascular invasion: Not definitively identified

Regional lymph nodes (pN): pN0. The hilar lymph nodes identified in part A, as well as the separately submitted lymph nodes in parts B, C, and D, are negative for tumor.

Distant metastasis (pM): pMX

Other findings: Emphysematous change with bleb formation in the upper lobe, with bronchiolar metaplasia, and subpleural fibrosis.

Note: This case has been reviewed in Intradepartmental Consultation with concurrence with the interpretation.

DIAGNOSIS

- A. Lung, right upper and middle lobes, excision
- Moderately differentiated adenocarcinoma, 3.2 cm in greatest dimension (pT2a), margins negative for malignancy (see microscopic description).
- Emphysematous changes, with bleb formation.
- Lymph nodes negative for malignancy.

- B,C,D. Lymph nodes, level 7, R4, and R2, excisions
- Negative for malignancy.
-

--- End Of Report ---

Source: NCI Genomic Data Commons file 313e1d02-1efb-4f63-9922-f8962e195e18 (TCGA-44-7671.BECECAB6-D442-4261-AB28-F4742E3828CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).